Somatic mutation profile of tumor specimen BA2273D (aliquot aq-BA2273D) from BEATAML1.0 case 2544, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,611 days).
Specimen BA2273D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4fdf815-5cb3-4fa0-909a-5d58ab3fba41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2475D (Solid Tissue Normal), aliquot aq-BA2475D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/712147aa-f537-47d7-abf8-1d64ec7790e7

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Splice Site 3, Silent 2, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 17/123 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 87/218 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP8B3 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs200167583; called by muse, mutect2, varscan2
- BCORL1 | c.3142C>T p.R1048* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV54391404; called by muse, mutect2, varscan2
- NRIP2 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 48/165 reads (29%) | catalogued as rs759845236, COSV61702041; called by muse, mutect2, varscan2
- TRIP12 | c.2353-6A>G | Splice Region (SNP) | VAF 34/101 reads (34%) | catalogued as rs375105358; called by muse, mutect2, varscan2
- AKR7A2 | c.791T>A p.F264Y | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATP8B3 | c.1841C>A p.T614N | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCOR | c.4819+1G>C p.X1607_splice (on ENST00000378444 / NM_001123385.2; = p.X1573_splice on NM_017745.6) | Splice Site (SNP) | VAF 80/127 reads (63%) | called by muse, mutect2, varscan2
- CD163 | c.3392T>C p.V1131A | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- COL6A3 | c.9A>C p.K3N | Missense Mutation (SNP) | VAF 67/383 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CS | c.1251G>T p.M417I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.301); called by muse, mutect2
- DNAH2 | c.12004G>A p.G4002S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JPH1 | c.640A>G p.R214G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NF1 | c.2990+2T>C p.X997_splice | Splice Site (SNP) | VAF 37/183 reads (20%) | called by muse, mutect2, varscan2
- PITPNB | c.*39-2A>G | Splice Site (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- SLC11A2 | c.1452A>G p.I484M (on ENST00000394904 / NM_001379455.1; = p.I455M on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- STEAP2 | c.968del p.L323Yfs*3 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- TAOK3 | c.1021del p.M341Wfs*15 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- OR9G1 | c.135C>T p.I45= | Silent (SNP) | VAF 18/346 reads (5%) | catalogued as rs751529792, COSV56451216; called by muse, mutect2
- TMEM63A | c.2142C>T p.H714= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs774228297; called by muse, mutect2, varscan2
- TMPO | chr12:98537616 T>A | 3'Flank (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- ZNF720 | c.361+1406A>G | Intron (SNP) | VAF 44/132 reads (33%) | called by muse, mutect2, varscan2
